Somatic mutation profile of tumor specimen TCGA-FR-A8YE-06A (aliquot TCGA-FR-A8YE-06A-11D-A372-08) from TCGA case TCGA-FR-A8YE, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 49.1 years (17,930 days).
Specimen TCGA-FR-A8YE-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bdebc9b0-a5ac-44bf-a5e9-20959c72628b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FR-A8YE-10A (Blood Derived Normal), aliquot TCGA-FR-A8YE-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a26d3a42-e519-4775-bf12-7074d6867e1e

The open-access MAF lists 375 somatic variants for this specimen: 244 protein-altering or splice-affecting, 124 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 223, Silent 124, Nonsense Mutation 11, Splice Region 6, 3'UTR 4, Splice Site 3, 5'Flank 2, Translation Start Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- A2ML1 | c.4082C>T p.S1361F | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV100229143; called by muse, varscan2
- ABCB1 | c.225G>A p.M75I | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.79); catalogued as COSV99713485; called by muse, mutect2, varscan2
- ABCG1 | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV100494323; called by muse, mutect2
- AC005324.2 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.855); catalogued as rs762320378, COSV60887139; called by muse, mutect2
- ACLY | c.2548C>T p.Q850* | Nonsense Mutation (SNP) | VAF 5/48 reads (10%) | catalogued as COSV61250383; called by mutect2, varscan2
- ADAT1 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV100329254; called by muse, mutect2
- ADCY10 | c.3837G>A p.M1279I | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100896949; called by muse, mutect2, varscan2
- ADGRV1 | c.16805C>T p.P5602L | Missense Mutation (SNP) | VAF 16/187 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.36); catalogued as COSV101316165; called by muse, mutect2
- AGBL2 | c.1324C>T p.P442S | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1414810597, COSV100101841; called by muse, mutect2, varscan2
- ANGPTL5 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.214); catalogued as rs940564532, COSV100527864; called by muse, mutect2
- ANK3 | c.7495G>A p.D2499N | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.07); catalogued as COSV99780821; called by muse, mutect2
- APBA1 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.398); catalogued as rs1430995132, COSV99596518; called by muse, mutect2
- APOB | c.12436G>A p.D4146N | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs778195760, COSV51925865; ClinVar: uncertain significance; called by muse, mutect2
- APOBEC4 | c.507G>A p.W169* | Nonsense Mutation (SNP) | VAF 5/79 reads (6%) | catalogued as COSV100426141; called by muse, mutect2
- APOD | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.012); catalogued as COSV58401843; called by muse, mutect2
- ARHGEF15 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); catalogued as COSV100730074; called by muse, mutect2, varscan2
- ATP2A2 | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100428740; called by muse, mutect2
- ATP2A2 | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100428744; called by muse, mutect2
- AXL | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV56568148, COSV56575983; called by muse, mutect2
- BICDL1 | c.1360C>T p.L454F | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV99985894; called by muse, mutect2
- BIRC6 | c.14090C>T p.S4697F | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101428441; called by muse, mutect2
- BRAT1 | c.1226C>T p.S409F | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1366267107, COSV61396796; called by muse, mutect2
- BRAT1 | c.712G>A p.V238M | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1275558356, COSV100500552; called by muse, mutect2, varscan2
- BRD2 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV100875743; called by muse, mutect2
- BRD2 | c.745C>A p.P249T | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV100875746; called by muse, mutect2
- BRPF3 | c.2644C>T p.L882F | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV100325990; called by muse, mutect2, varscan2
- C17orf98 | c.211C>T p.H71Y | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.204); catalogued as rs1359648743; called by muse, mutect2
- C2orf69 | c.455G>A p.C152Y | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV100178887; called by muse, mutect2
- C4orf50 | c.225G>A p.K75= (on ENST00000324058; = p.K1307= on NM_001364689.1 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 8/94 reads (9%) | catalogued as COSV100136009; called by muse, mutect2
- C8B | c.949T>A p.F317I | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as COSV100980809; called by muse, mutect2, varscan2
- CABS1 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV99909105; called by muse, mutect2, varscan2
- CACNA1A | c.3958G>A p.D1320N | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1568485068, COSV64196778; ClinVar: uncertain significance; called by muse, mutect2
- CACNG3 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50083751, COSV99135606; called by muse, mutect2
- CAPSL | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 16/231 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101274287; called by muse, mutect2
- CASC3 | c.823G>A p.G275S | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs748066451, COSV52866312, COSV99229839; called by muse, mutect2
- CATSPERB | c.1679C>T p.P560L | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs766533645, COSV99831467; called by muse, mutect2
- CBLIF | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99951010; called by muse, mutect2
- CCDC60 | c.762G>A p.M254I | Missense Mutation (SNP) | VAF 18/241 reads (7%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.986); catalogued as COSV59550353; called by muse, mutect2
- CD300C | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT tolerated (0.85); PolyPhen benign (0.102); catalogued as COSV100423282; called by muse, mutect2
- CD5L | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.677); catalogued as COSV100941087; called by muse, mutect2
- CDCA7 | c.974G>A p.G325E (on ENST00000347703 / NM_145810.3; = p.G404E on NM_031942.5) | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as COSV100143612; called by muse, mutect2, varscan2
- CDH8 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.07); catalogued as rs1402228461, COSV100182781; called by muse, mutect2
- CEACAM6 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as rs782022161, COSV52266484, COSV52266573, COSV52267133; called by muse, mutect2, varscan2
- CIBAR2 | c.382C>G p.L128V | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV101608288; called by muse, mutect2, varscan2
- CLASP1 | c.90T>A p.Y30* | Nonsense Mutation (SNP) | VAF 8/78 reads (10%) | catalogued as COSV99755727; called by muse, mutect2, varscan2
- CLGN | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV100346708; called by muse, mutect2, varscan2
- CMYA5 | c.5674G>A p.E1892K | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV101484170; called by muse, mutect2
- CNGA1 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV100652269; called by muse, mutect2, varscan2
- CNMD | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.265); catalogued as COSV100937284; called by muse, mutect2
- CNTNAP2 | c.1343C>T p.S448F | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs747014037, COSV62195484; called by muse, mutect2
- COL14A1 | c.4687G>A p.G1563R | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as rs1213141280, COSV99919834; called by muse, mutect2, varscan2
- COL1A1 | c.792G>A p.M264I | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99867635; called by muse, mutect2, varscan2
- COL4A4 | c.2164+1G>A p.X722_splice | Splice Site (SNP) | VAF 8/63 reads (13%) | catalogued as COSV100307222; called by muse, mutect2, varscan2
- COL9A1 | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.284); catalogued as COSV100611670; called by muse, mutect2
- CUX1 | c.2513C>T p.S838F | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as COSV52916657; called by muse, mutect2, varscan2
- CWH43 | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99893642; called by muse, mutect2
- CYP2C18 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV99608694; called by muse, mutect2, varscan2
- DAAM1 | c.2102C>T p.S701L | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781776500, COSV100658523; called by muse, mutect2
- DELE1 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.068); catalogued as COSV52004404; called by muse, mutect2, varscan2
- DGKI | c.511-1G>A p.X171_splice | Splice Site (SNP) | VAF 41/180 reads (23%) | catalogued as COSV99935739; called by muse, mutect2, varscan2
- DHX30 | c.433C>T p.R145C (on ENST00000445061 / NM_138615.3; = p.R106C on NM_014966.3) | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.421); catalogued as COSV100820072; called by muse, mutect2, varscan2
- DHX58 | c.625G>T p.E209* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as COSV99288358; called by muse, mutect2, varscan2
- DNAH5 | c.6226G>A p.E2076K | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99451452; called by muse, mutect2
- DSC3 | c.1796C>T p.P599L | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV64573074; called by muse, mutect2
- DSCAM | c.3691C>T p.P1231S | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.975); catalogued as COSV101260742; called by muse, mutect2
- DSG4 | c.87G>A p.V29= | Splice Region (SNP) | VAF 9/94 reads (10%) | catalogued as CD078493, COSV57398370; called by mutect2, varscan2
- DZIP3 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.437); catalogued as COSV100847901; called by muse, mutect2
- ECE1 | c.1901C>T p.S634F | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51664673; called by muse, mutect2
- EGFLAM | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); catalogued as COSV100380475; called by muse, mutect2
- ENAM | c.1873G>A p.D625N | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.221); catalogued as COSV101253212; called by muse, mutect2
- ENPP4 | c.555G>A p.W185* | Nonsense Mutation (SNP) | VAF 22/144 reads (15%) | catalogued as COSV100320378; called by muse, mutect2, varscan2
- EP400 | c.5309C>T p.S1770F | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.046); catalogued as COSV57764182; called by muse, mutect2, varscan2
- EPHA3 | c.2462G>A p.G821E | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100346586; called by muse, mutect2
- EPHB4 | c.1247C>T p.A416V | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.636); catalogued as COSV100639562; called by muse, mutect2
- EPS15 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100869567; called by muse, mutect2, varscan2
- EPS8L3 | c.749A>G p.E250G | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100719728; called by muse, mutect2
- ERICH3 | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 32/334 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs267598720, COSV58611092; called by muse, mutect2
- ESRP1 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776222018, COSV100619420; called by muse, mutect2, varscan2
- EXOC4 | c.2512C>T p.Q838* | Nonsense Mutation (SNP) | VAF 7/149 reads (5%) | catalogued as COSV99554621; called by muse, mutect2
- F13B | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs969352952, COSV66376040; called by muse, mutect2
- F3 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100474335; called by muse, mutect2
- F5 | c.6140G>A p.R2047Q | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as rs748256909, COSV100889165; called by muse, mutect2
- FABP1 | c.377G>A p.R126K | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.108); catalogued as COSV99860922; called by muse, mutect2, varscan2
- FAM120C | c.2996C>T p.T999I | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100070248; called by muse, mutect2, varscan2
- FAM47A | c.1552C>T p.R518C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs17855514, COSV60495273, COSV60497171; called by muse, varscan2
- FAM47C | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs147613870, COSV63727652; called by muse, mutect2, varscan2
- FAM81A | c.163A>G p.K55E | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99893386; called by muse, mutect2, varscan2
- FAM83B | c.2788G>A p.D930N | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100174644; called by muse, mutect2, varscan2
- FATE1 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.082); catalogued as rs759629114, COSV64848903, COSV64849200; called by muse, mutect2, varscan2
- FGF19 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV53736424; called by muse, mutect2
- FGFR4 | c.2369G>A p.G790E | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV99450342; called by muse, mutect2
- FLG | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 59/446 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.155); catalogued as rs149884927, COSV64247011; called by muse, mutect2, varscan2
- FMNL1 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs760805391, COSV100056697; called by mutect2, varscan2
- FUS | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.428); catalogued as COSV54216654; called by muse, mutect2
- GABRA2 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100734518; called by muse, mutect2, varscan2
- GABRB2 | c.1486C>A p.P496T (on ENST00000274547; = p.P458T on NM_000813.3) | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99196283; called by muse, mutect2, varscan2
- GABRG2 | c.947C>T p.T316I (on ENST00000361925 / NM_001375343.1; = p.T276I on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV100729758; called by muse, mutect2
- GALNT16 | c.1472C>T p.S491F | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100546039; called by muse, mutect2, varscan2
- GART | c.1357A>G p.K453E | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.85); PolyPhen benign (0.028); catalogued as COSV100738216; called by muse, mutect2, varscan2
- GCNA | c.717T>G p.S239R | Missense Mutation (SNP) | VAF 54/278 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as COSV101032574; called by muse, varscan2
- GJB4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100258553; called by muse, mutect2
- H2AC4 | c.113G>A p.G38D | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99451514, COSV99451574; called by muse, mutect2, varscan2
- HACE1 | c.1991G>A p.R664Q | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99493952; called by muse, mutect2
- HAS1 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.187); catalogued as rs769183113, COSV55787577, COSV55790326, COSV99708591; called by muse, mutect2, varscan2
- HEATR1 | c.1865C>T p.A622V | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.377); catalogued as COSV100857703; called by muse, mutect2
- HECW1 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101223960; called by muse, mutect2, varscan2
- HS3ST4 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 19/241 reads (8%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as rs867965756, COSV58804388; called by muse, mutect2
- IL4R | c.1393C>T p.L465F | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV99405164; called by muse, mutect2, varscan2
- IL7R | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.121); catalogued as COSV57407706; called by muse, mutect2
- INTS4 | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV101417224; called by muse, mutect2, varscan2
- ITGAE | c.2380C>T p.P794S | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs1293701350, COSV99561216; called by muse, mutect2, varscan2
- ITSN2 | c.931A>T p.M311L | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.345); catalogued as COSV100743837; called by muse, mutect2
- KMT5A | c.169T>G p.Y57D | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.503); catalogued as COSV100389548; called by muse, mutect2, varscan2
- L3MBTL1 | c.1579C>T p.P527S (on ENST00000418998 / NM_001377303.1; = p.P437S on NM_015478.7) | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64229349; called by muse, mutect2, varscan2
- LCE1E | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); catalogued as COSV64219498; called by muse, mutect2
- LCE1E | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); catalogued as rs1268126678, COSV100908559; called by muse, mutect2
- LIPI | c.286A>G p.K96E | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1321811006, COSV100753824; called by muse, mutect2, varscan2
- LRP1B | c.8224G>A p.E2742K | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.829); catalogued as rs1263526417, COSV101257992; called by muse, mutect2
- LRP6 | c.4322G>A p.R1441Q | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.439); catalogued as rs1421164704, COSV99743759; called by muse, mutect2
- LRRC3B | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs868070081, COSV67522078; called by muse, mutect2, varscan2
- LRRC4C | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as COSV53418301, COSV99538823; called by muse, mutect2
- MAGEC1 | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.448); catalogued as COSV53576069; called by muse, mutect2, varscan2
- MAMDC2 | c.1352G>A p.R451K | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.06); catalogued as COSV101015574; called by muse, mutect2, varscan2
- MAP3K14 | c.1886C>T p.A629V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.113); catalogued as COSV100766514; called by muse, mutect2
- MED6 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV99833018; called by muse, mutect2
- MFSD2A | c.359C>T p.S120F (on ENST00000372809 / NM_001136493.3; = p.S107F on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100861711; called by muse, mutect2
- MPDU1 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV51469980; called by muse, mutect2
- MROH2B | c.995G>A p.G332E | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.659); catalogued as COSV101270789; called by muse, mutect2
- MSR1 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV50534409; called by muse, mutect2, varscan2
- MTMR8 | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs768821897, COSV100878478; called by muse, mutect2, varscan2
- MUC16 | c.34031C>T p.S11344L | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.047); catalogued as COSV101199166; called by muse, mutect2, varscan2
- MUC16 | c.1898C>T p.S633L | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV67453066; called by muse, mutect2
- MUC17 | c.4177G>A p.E1393K | Missense Mutation (SNP) | VAF 30/449 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1391737103, COSV60295664; called by muse, mutect2
- MYH1 | c.3616G>A p.E1206K | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs375020058; called by muse, mutect2
- MYH7 | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as rs1268553099, COSV62519896; called by muse, mutect2
- MYLK | c.2450G>A p.R817K | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100659289; called by muse, mutect2, varscan2
- MYO10 | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0.134); catalogued as COSV101549860, COSV101549875; called by muse, mutect2
- NCSTN | c.839C>T p.T280I | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV99667313; called by muse, mutect2
- NELL1 | c.1855G>A p.G619S | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.249); catalogued as COSV100122568; called by muse, mutect2
- NIPBL | c.976C>G p.Q326E | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); catalogued as COSV56965221, COSV99241306; called by muse, mutect2
- NIPBL | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs1172471352, COSV99241310; called by muse, mutect2, varscan2
- NKAIN3 | c.320G>A p.W107* | Nonsense Mutation (SNP) | VAF 9/72 reads (13%) | catalogued as COSV60691404; called by muse, mutect2, varscan2
- NLRP11 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV64087243; called by muse, mutect2, varscan2
- NOMO1 | c.3604T>A p.S1202T | Missense Mutation (SNP) | VAF 34/702 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.142); catalogued as COSV99814646; called by muse, mutect2
- NOTCH3 | c.2492G>A p.G831E | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54627360; called by muse, mutect2
- NPAP1 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.801); catalogued as rs868115699, COSV61504054; called by muse, mutect2
- NPC1L1 | c.1429C>T p.P477S | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56927059, COSV99203056; called by muse, mutect2, varscan2
- NPHP1 | c.1138C>T p.R380C (on ENST00000393272 / NM_207181.4; = p.R381C on NM_000272.5) | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748435719, COSV100338263; called by muse, mutect2, varscan2
- NPPA | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.15); catalogued as COSV56741541; called by muse, mutect2, varscan2
- NSD1 | c.1307G>A p.G436E | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV100729556; called by muse, mutect2, varscan2
- OAS2 | c.1999C>T p.P667S | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV60802341; called by muse, mutect2
- ODC1 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV99301334; called by muse, mutect2
- OPTN | c.1456C>T p.H486Y | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as rs1564368754, COSV99537617; called by muse, mutect2
- OR10A6 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV59164741; called by muse, mutect2, varscan2
- OR10K2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs111878656, COSV59220924; called by muse, mutect2
- OR2L3 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); catalogued as COSV63455228; called by muse, mutect2
- OR2T3 | c.222G>A p.M74I | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV100613291; called by muse, mutect2
- OR51B2 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60916252, COSV60918089; called by muse, mutect2
- OR8I2 | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV56170774; called by muse, mutect2
- P2RY14 | c.384G>A p.W128* | Nonsense Mutation (SNP) | VAF 14/80 reads (18%) | catalogued as rs1437864352, COSV99853784; called by muse, mutect2, varscan2
- PCDHB4 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs150738461; called by muse, mutect2
- PCDHB7 | c.2090C>T p.S697L | Missense Mutation (SNP) | VAF 20/334 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.239); catalogued as COSV50774843; called by muse, mutect2
- PCDHGA3 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.185); catalogued as rs267600447, COSV54043100; called by muse, mutect2, varscan2
- PCLO | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs779306007, COSV100434408; called by muse, mutect2, varscan2
- PCNX2 | c.4580G>A p.R1527K | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as COSV99268466; called by muse, mutect2
- PCNX4 | c.1885C>T p.Q629* (on ENST00000406854 / NM_001330177.2; = p.Q395* on NM_022495.5) | Nonsense Mutation (SNP) | VAF 3/40 reads (8%) | catalogued as COSV100470403, COSV100470521; called by muse, mutect2
- PENK | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs770322157, COSV100152399; called by muse, mutect2, varscan2
- PILRA | c.708G>A p.R236= | Splice Region (SNP) | VAF 18/82 reads (22%) | catalogued as COSV52202490; called by muse, mutect2, varscan2
- PKD1L1 | c.3437C>T p.S1146F | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV99220504; called by muse, mutect2, varscan2
- PKHD1 | c.10595G>A p.G3532D | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100944650, COSV64382972; called by muse, mutect2, varscan2
- PKN2 | c.2503A>T p.T835S | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV100981394; called by muse, mutect2
- PLEKHA7 | c.2329G>A p.E777K | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs201494675, COSV63046349; called by muse, mutect2
- PLEKHB2 | c.623G>T p.G208V (on ENST00000409279; = p.G207V on NM_017958.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99301741; called by muse, mutect2
- PLEKHG6 | c.1351G>A p.V451I | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV50619150, COSV99164442; called by muse, mutect2, varscan2
- POLR1E | c.272C>A p.S91Y (on ENST00000377792 / NM_001282766.1; = p.S29Y on NM_022490.4) | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1240465333, COSV100905417; called by muse, mutect2
- PRKG1 | c.835G>A p.G279R | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100907294, COSV64769727; called by muse, mutect2
- PRR23B | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs768770380, COSV61494861; called by muse, mutect2, varscan2
- PSG9 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 30/289 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.19); catalogued as COSV52483953, COSV99392421; called by muse, mutect2, varscan2
- PTPRC | c.421G>A p.G141S | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.009); catalogued as COSV100722819; called by muse, mutect2
- RASSF9 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 24/237 reads (10%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.736); catalogued as COSV99057140; called by muse, mutect2, varscan2
- RHOT1 | c.461A>G p.N154S | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100447397; called by muse, mutect2
- RIN1 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as rs545135172; called by muse, mutect2, varscan2
- RIN1 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.452); catalogued as rs747145659, COSV100254774; called by muse, mutect2, varscan2
- RLN1 | c.338A>G p.Q113R | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.876); catalogued as rs763648751, COSV99802769; called by muse, mutect2, varscan2
- RLN1 | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 14/116 reads (12%) | catalogued as COSV99802772; called by muse, mutect2, varscan2
- RSF1 | c.4117G>A p.G1373R | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as COSV100407445; called by muse, mutect2, varscan2
- RTP5 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.703); catalogued as COSV100574766; called by muse, mutect2, varscan2
- RYR1 | c.5728G>A p.E1910K | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV62103479; called by muse, mutect2, varscan2
- SACS | c.6188C>T p.P2063L | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); catalogued as COSV101207533; called by muse, mutect2, varscan2
- SAFB2 | c.543T>G p.A181= | Splice Region (SNP) | VAF 4/67 reads (6%) | catalogued as COSV99385857; called by muse, mutect2
- SCN1A | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100321094; called by muse, mutect2, varscan2
- SELP | c.1555G>A p.G519R | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55257590; called by muse, mutect2, varscan2
- SERPINA3 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101261748; called by muse, mutect2, varscan2
- SERPINB4 | c.1025A>T p.E342V | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100345824; called by muse, mutect2, varscan2
- SH2D3A | c.920G>A p.G307D | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99838087; called by muse, mutect2
- SIAH3 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV101247934; called by muse, mutect2
- SLC12A3 | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM166517, COSV99344443; called by muse, mutect2, varscan2
- SLC1A3 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as rs753529094, COSV54318652; called by muse, mutect2
- SLC29A4 | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99786861; called by muse, mutect2
- SLC4A8 | c.2063G>A p.G688E | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV60648616; called by muse, mutect2, varscan2
- SLC5A1 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as rs143443198, COSV56689766; called by muse, mutect2, varscan2
- SLC8A3 | c.736C>T p.L246F | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV100776285; called by muse, mutect2, varscan2
- SLCO1C1 | c.1529A>G p.N510S | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99859441; called by muse, mutect2
- SNCAIP | c.1423-1G>A p.X475_splice | Splice Site (SNP) | VAF 8/154 reads (5%) | catalogued as COSV99749416; called by muse, mutect2
- SPHK2 | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.96); catalogued as COSV99709456; called by muse, mutect2
- SPIRE1 | c.2045C>T p.S682L (on ENST00000409402 / NM_001128626.2; = p.S668L on NM_020148.3) | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs1334853790, COSV100563817, COSV59156509; called by muse, mutect2, varscan2
- SRGAP3 | c.1696G>A p.D566N | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV100841089; called by muse, mutect2
- ST14 | c.1840C>T p.R614C | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53831716; called by muse, mutect2
- ST7 | c.1465C>T p.P489S (on ENST00000393443 / NM_001369607.1; = p.P544S on NM_018412.4) | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.96); catalogued as COSV60646645; called by muse, mutect2
- STAT4 | c.273G>A p.Q91= | Splice Region (SNP) | VAF 11/71 reads (15%) | catalogued as COSV100636110; called by muse, mutect2, varscan2
- STK38L | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV66522564; called by muse, mutect2
- STYXL2 | c.2707A>C p.N903H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.498); catalogued as COSV99609499; called by mutect2, varscan2
- TBL1X | c.1571C>T p.S524F | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99482800; called by muse, mutect2, varscan2
- TBX4 | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV53607130; called by muse, mutect2, varscan2
- TCF20 | c.2473A>G p.S825G | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs769706529, COSV100166746; called by muse, mutect2, varscan2
- TEX14 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.236); catalogued as COSV53620615; called by muse, mutect2
- TMCC3 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as rs370011735, COSV54158065; called by muse, mutect2, varscan2
- TMEM132B | c.2368G>A p.E790K | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.161); catalogued as rs746605414, COSV100168718, COSV54747217; called by muse, mutect2, varscan2
- TMEM132D | c.1468T>G p.F490V | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV101242949; called by muse, mutect2, varscan2
- TMEM67 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as COSV100019569; called by muse, mutect2
- TMX2 | c.313T>G p.F105V | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99560153; called by muse, mutect2, varscan2
- TPRG1 | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.87); PolyPhen benign (0.005); catalogued as rs773595473, COSV100800630, COSV61464286; called by muse, mutect2, varscan2
- TPTE2 | c.259G>A p.D87N (on ENST00000400230 / NM_199254.2; = p.D50N on NM_130785.3) | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as COSV55022663, COSV99690589; called by muse, mutect2
- TRIM14 | c.440A>G p.Q147R | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as rs1298640776, COSV100419634; called by muse, mutect2, varscan2
- TRIM69 | c.779A>T p.K260M (on ENST00000329464 / NM_182985.5; = p.K101M on NM_080745.5) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV100274319; called by muse, mutect2, varscan2
- TRIM69 | c.780G>T p.K260N (on ENST00000329464 / NM_182985.5; = p.K101N on NM_080745.5) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV100274320; called by muse, mutect2, varscan2
- TRPS1 | c.3365C>T p.P1122L (on ENST00000220888 / NM_001330599.2; = p.P1135L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV99632184; called by muse, mutect2
- TSSK1B | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs201361921; called by muse, mutect2, varscan2
- TTN | c.50359G>A p.D16787N (on ENST00000591111; = p.D9363N on NM_003319.4) | Missense Mutation (SNP) | VAF 7/82 reads (9%) | PolyPhen benign (0); catalogued as COSV100619848; called by muse, mutect2
- TUBA1C | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV99988862; called by muse, mutect2
- UHRF1BP1L | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as rs766723484, COSV54437555; called by muse, mutect2, varscan2
- UNC79 | c.1637G>A p.G546E (on ENST00000393151 / NM_001346218.2; = p.G369E on NM_020818.5) | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT tolerated (0.39); PolyPhen probably damaging (1); catalogued as COSV99828602; called by muse, mutect2
- VSIG10 | c.715T>C p.F239L | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs767709728, COSV100821323; called by muse, mutect2
- VWF | c.4942C>T p.P1648S | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs61750590, CM920714, COSV99779522; ClinVar: not provided; called by muse, mutect2, varscan2
- WNT3A | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.792); catalogued as COSV99469758; called by muse, mutect2, varscan2
- ZDBF2 | c.5746C>T p.P1916S | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.035); catalogued as COSV100985110; called by muse, mutect2
- ZFAT | c.1873C>T p.Q625* | Nonsense Mutation (SNP) | VAF 15/120 reads (13%) | catalogued as COSV100914758; called by muse, mutect2, varscan2
- ZNF430 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.076); catalogued as COSV99841856; called by muse, mutect2
- ZPLD1 | c.722G>A p.G241E (on ENST00000466937 / NM_001329788.1; = p.G257E on NM_175056.2) | Missense Mutation (SNP) | VAF 15/171 reads (9%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.934); catalogued as COSV60351939; called by muse, mutect2
- HCK | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PTPN20 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 9/197 reads (5%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- SMTNL1 | c.621+7G>A | Splice Region (SNP) | VAF 4/55 reads (7%) | called by muse, mutect2
- ZNF280A | c.551G>A p.R184K | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AC005324.2 | c.930C>T p.I310= | Silent (SNP) | VAF 10/138 reads (7%) | catalogued as COSV100371979; called by muse, mutect2
- ACLY | c.42C>T p.L14= | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as rs993301912, COSV100709776; called by muse, mutect2
- ADAM29 | c.1248A>G p.L416= | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as rs775690796, COSV100822099; called by muse, mutect2, varscan2
- ADGRG4 | c.6996C>T p.V2332= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as COSV54961976, COSV99795970; called by muse, mutect2, varscan2
- AGMAT | c.570G>A p.T190= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as rs748259944, COSV65435883; called by muse, mutect2, varscan2
- AGTR2 | c.60C>T p.F20= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs782532455, COSV100903589; called by muse, mutect2, varscan2
- ANK3 | c.3471C>T p.T1157= (on ENST00000280772 / NM_001320874.2; = p.T291= on NM_001149.3) | Silent (SNP) | VAF 12/142 reads (8%) | catalogued as rs768718440, COSV99780825; called by muse, mutect2
- ARC | c.1077G>A p.L359= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV100751745; called by muse, mutect2
- ARHGAP44 | c.681G>A p.R227= | Silent (SNP) | VAF 9/139 reads (6%) | catalogued as COSV99311048; called by muse, mutect2
- ARVCF | c.463C>T p.L155= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV99599384; called by muse, mutect2, varscan2
- ATP1A2 | c.705G>A p.L235= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as rs1019036534, COSV100767943; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATP1A3 | c.1806C>T p.V602= (on ENST00000545399 / NM_001256214.2; = p.V589= on NM_152296.5) | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV100132375; called by muse, mutect2
- ATP1A4 | c.733C>T p.L245= | Silent (SNP) | VAF 16/119 reads (13%) | catalogued as COSV63628207; called by muse, mutect2, varscan2
- BICDL1 | c.1362C>T p.L454= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV99985897; called by muse, mutect2
- BRPF3 | c.3597C>T p.F1199= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs375841400; called by muse, mutect2, varscan2
- C2orf16 | c.1086G>A p.V362= | Silent (SNP) | VAF 5/74 reads (7%) | catalogued as rs1479097130, COSV101284400; called by muse, mutect2
- C6 | c.1470C>T p.I490= | Silent (SNP) | VAF 10/107 reads (9%) | catalogued as rs760389028, COSV54705258, COSV54712571; called by muse, mutect2, varscan2
- CACNG3 | c.645C>T p.F215= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as COSV50064374; called by muse, mutect2, varscan2
- CATSPERD | c.834G>A p.V278= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV67534310; called by muse, mutect2
- CDH6 | c.933G>A p.E311= | Silent (SNP) | VAF 5/94 reads (5%) | catalogued as COSV99419837, COSV99420111; called by muse, mutect2
- CDH9 | c.1239G>A p.R413= | Silent (SNP) | VAF 6/112 reads (5%) | catalogued as rs866802321, COSV50542064; called by muse, mutect2
- CECR2 | c.1266C>T p.S422= (on ENST00000342247 / NM_001290047.2; = p.S239= on NM_001290046.1) | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as COSV99378488; called by muse, mutect2
- CFAP94 | c.366G>A p.E122= (on ENST00000320267 / NM_001352064.2; = p.E128= on NM_018272.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as COSV100209522; called by muse, mutect2, varscan2
- CNKSR1 | c.1539C>T p.P513= (on ENST00000374253 / NM_001297647.2; = p.P506= on NM_006314.3) | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV58792255, COSV58794623; called by muse, mutect2, varscan2
- CRAMP1 | c.3060C>T p.I1020= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV99246172; called by muse, mutect2
- CTSC | c.1323C>T p.I441= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as rs372847740; called by muse, mutect2, varscan2
- DACT1 | c.2298C>T p.F766= | Silent (SNP) | VAF 11/139 reads (8%) | catalogued as rs781117085, COSV60020531; called by muse, mutect2
- DDX47 | c.828C>T p.T276= | Silent (SNP) | VAF 15/169 reads (9%) | catalogued as COSV100774596; called by muse, mutect2
- DEFB125 | c.240G>A p.L80= | Silent (SNP) | VAF 25/215 reads (12%) | catalogued as COSV101217553; called by muse, mutect2, varscan2
- DNAH2 | c.1995C>G p.A665= | Silent (SNP) | VAF 46/364 reads (13%) | catalogued as rs377589071; called by muse, mutect2, varscan2
- DNAH3 | c.3981G>A p.G1327= | Silent (SNP) | VAF 4/64 reads (6%) | catalogued as COSV99768735; called by muse, mutect2
- DNAH5 | c.3589C>T p.L1197= | Silent (SNP) | VAF 14/165 reads (8%) | catalogued as COSV54204094, COSV54204226, COSV54248432; called by muse, mutect2
- DNAH5 | c.3471G>A p.K1157= | Silent (SNP) | VAF 7/128 reads (5%) | catalogued as rs865979045, COSV99451458; ClinVar: likely benign; called by muse, mutect2
- DOCK4 | c.5820C>T p.S1940= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs1233578856, COSV101447902; called by muse, mutect2, varscan2
- DOK5 | c.195G>A p.V65= | Silent (SNP) | VAF 12/133 reads (9%) | catalogued as COSV52822237; called by muse, mutect2
- EPHA8 | c.1782C>T p.F594= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as rs750902137, COSV51272084; called by muse, mutect2, varscan2
- EXO1 | c.2514C>T p.G838= | Silent (SNP) | VAF 7/143 reads (5%) | catalogued as COSV100799959; called by muse, mutect2
- F3 | c.547T>C p.L183= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV100474333; called by muse, mutect2, varscan2
- FAM47C | c.435C>T p.L145= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV100792771; called by muse, mutect2
- GAB3 | c.252C>T p.F84= | Silent (SNP) | VAF 20/125 reads (16%) | catalogued as rs1557257582, COSV65818892; called by muse, mutect2, varscan2
- GABRG2 | c.1101C>A p.P367= (on ENST00000361925 / NM_001375343.1; = p.P327= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/146 reads (4%) | catalogued as COSV100729759; called by muse, mutect2
- GPR37L1 | c.801C>T p.L267= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs114000176, COSV100938568; called by muse, mutect2, varscan2
- GRIN2B | c.2889C>T p.I963= | Silent (SNP) | VAF 15/123 reads (12%) | catalogued as COSV101663109; called by muse, mutect2, varscan2
- HECW1 | c.135C>T p.P45= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV101223961; called by muse, mutect2, varscan2
- HLA-DQA1 | c.489C>T p.F163= | Silent (SNP) | VAF 14/129 reads (11%) | catalogued as COSV100568160; called by muse, mutect2, varscan2
- HSPA13 | c.1410C>T p.F470= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV53464660; called by muse, mutect2
- IGHA1 | c.918G>A p.K306= | Silent (SNP) | VAF 6/108 reads (6%) | catalogued as rs773917605; called by muse, mutect2
- IGKV1D-17 | c.189G>A p.G63= | Silent (SNP) | VAF 27/257 reads (11%) | called by muse, mutect2, varscan2
- IL10RB | c.210C>T p.T70= | Silent (SNP) | VAF 9/140 reads (6%) | catalogued as COSV99270076; called by muse, mutect2
- ITPKB | c.1377A>C p.A459= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV99684733; called by muse, mutect2
- JADE1 | c.1008C>T p.A336= | Silent (SNP) | VAF 15/145 reads (10%) | catalogued as COSV56907816; called by muse, mutect2, varscan2
- KCNC3 | c.1362C>T p.F454= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs369120661, COSV100979304; called by muse, mutect2, varscan2
- KCND3 | c.1881G>A p.G627= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV56192574; called by muse, mutect2
- KHDC3L | c.189C>T p.I63= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV64868955; called by muse, mutect2, varscan2
- KIF13A | c.4425G>A p.E1475= | Silent (SNP) | VAF 31/288 reads (11%) | catalogued as COSV52445679, COSV99436729; called by muse, mutect2, varscan2
- KRTAP26-1 | c.72C>T p.L24= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV100860441, COSV62128422; called by muse, mutect2, varscan2
- MAP3K13 | c.1152C>T p.I384= | Silent (SNP) | VAF 9/129 reads (7%) | catalogued as COSV53985019, COSV53991053; called by muse, mutect2
- MAST4 | c.5550G>A p.K1850= (on ENST00000403625 / NM_001164664.2; = p.K1661= on NM_015183.3) | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV99844786; called by muse, mutect2, varscan2
- MORC1 | c.1251T>C p.F417= | Silent (SNP) | VAF 16/134 reads (12%) | catalogued as rs1382139613, COSV99226784; called by muse, mutect2, varscan2
- MORN3 | c.528C>T p.F176= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV100804485; called by muse, mutect2, varscan2
- MUC16 | c.24558C>T p.L8186= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as rs1287973844, COSV67485482; called by muse, mutect2, varscan2
- MYH13 | c.5748C>T p.I1916= | Silent (SNP) | VAF 20/158 reads (13%) | catalogued as rs767194192, COSV99354557; called by muse, mutect2, varscan2
- MYH14 | c.5277G>A p.E1759= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV99223316; called by muse, mutect2
- MYO18B | c.2724G>A p.V908= | Silent (SNP) | VAF 6/126 reads (5%) | catalogued as rs1466162177, COSV100124259; called by muse, mutect2
- NACA2 | c.597G>A p.L199= | Silent (SNP) | VAF 22/232 reads (9%) | catalogued as COSV101478563; called by muse, mutect2
- NLRP9 | c.1336C>T p.L446= | Silent (SNP) | VAF 20/150 reads (13%) | catalogued as COSV100243202, COSV60461061; called by muse, mutect2, varscan2
- NUMA1 | c.1635C>T p.A545= | Silent (SNP) | VAF 19/244 reads (8%) | catalogued as COSV61191395; called by muse, mutect2
- OR10S1 | c.459G>A p.R153= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV73342677; called by muse, mutect2, varscan2
- OR12D2 | c.516C>T p.I172= | Silent (SNP) | VAF 14/158 reads (9%) | catalogued as COSV101011361; called by muse, mutect2
- OR4D5 | c.865C>T p.L289= | Silent (SNP) | VAF 8/133 reads (6%) | catalogued as COSV100190058; called by muse, mutect2
- OR5F1 | c.801C>T p.S267= | Silent (SNP) | VAF 7/99 reads (7%) | catalogued as rs1481820605, COSV99558443, COSV99558733; called by muse, mutect2
- OR5F1 | c.150G>A p.R50= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV99558736, COSV99558901; called by muse, mutect2, varscan2
- OR6C75 | c.306C>T p.F102= | Silent (SNP) | VAF 14/208 reads (7%) | catalogued as COSV58553403; called by muse, mutect2
- OR8H3 | c.252G>A p.A84= | Silent (SNP) | VAF 48/439 reads (11%) | catalogued as rs552621074, COSV57908346; called by muse, mutect2, varscan2
- OR8J1 | c.438C>T p.S146= | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as COSV57317481; called by muse, mutect2
- PAPPA | c.2898C>T p.I966= | Silent (SNP) | VAF 10/167 reads (6%) | catalogued as COSV100074614, COSV60277562; called by muse, mutect2
- PARP4 | c.823C>T p.L275= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV101131784; called by muse, mutect2, varscan2
- PCDHA1 | c.351C>T p.F117= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as rs1554117490, COSV65373297; called by muse, mutect2
- PCNX3 | c.3579C>T p.F1193= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV100856514; called by muse, mutect2, varscan2
- PCSK6 | c.558C>T p.V186= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV100083717; called by muse, mutect2, varscan2
- PDE8B | c.2286G>A p.G762= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV99367092; called by muse, mutect2
- PEAR1 | c.2730G>A p.E910= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV99441806; called by muse, mutect2, varscan2
- PPP2R2B | c.435C>T p.I145= (on ENST00000394409; = p.I211= on NM_181674.2) | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV100355286; called by muse, mutect2
- PRSS12 | c.1893C>T p.I631= | Silent (SNP) | VAF 8/134 reads (6%) | catalogued as COSV99628502; called by muse, mutect2
- PSMD5 | c.900C>A p.V300= | Silent (SNP) | VAF 14/146 reads (10%) | catalogued as COSV99270867; called by muse, mutect2
- PTX4 | c.1029G>A p.G343= (on ENST00000447419 / NM_001328608.2; = p.G338= on NM_001013658.1) | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV99560610; called by muse, mutect2, varscan2
- RALGAPA2 | c.5235C>T p.V1745= | Silent (SNP) | VAF 11/147 reads (7%) | catalogued as COSV99174056; called by muse, mutect2
- RANBP3 | c.1104C>T p.S368= (on ENST00000340578 / NM_007322.3; = p.S363= on NM_003624.3) | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV50383339; called by muse, mutect2, varscan2
- RBPJ | c.495C>T p.S165= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as COSV100623674; called by muse, mutect2, varscan2
- REXO1 | c.2838C>T p.F946= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV99402465; called by muse, mutect2
- RGS6 | c.315G>A p.K105= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as rs543989269, COSV59598786, COSV99052594; called by muse, mutect2, varscan2
- RICTOR | c.4677C>T p.I1559= | Silent (SNP) | VAF 17/161 reads (11%) | catalogued as COSV57117091; called by muse, mutect2
- SCG5 | c.327G>A p.E109= | Silent (SNP) | VAF 11/180 reads (6%) | catalogued as COSV100276843, COSV55707726; called by muse, mutect2
- SCN2A | c.1827C>T p.D609= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as rs780387055, COSV99332362; called by mutect2, varscan2
- SFTPD | c.795C>T p.F265= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV64852777; called by muse, mutect2
- SGIP1 | c.1506G>A p.R502= | Silent (SNP) | VAF 20/196 reads (10%) | catalogued as COSV99392093; called by muse, mutect2, varscan2
- SI | c.396G>A p.R132= | Silent (SNP) | VAF 10/119 reads (8%) | catalogued as COSV100016218, COSV52275600; called by muse, mutect2
- SLC22A3 | c.630C>T p.I210= | Silent (SNP) | VAF 13/198 reads (7%) | catalogued as COSV99279164; called by muse, mutect2
- SLC7A8 | c.270C>T p.A90= | Silent (SNP) | VAF 30/253 reads (12%) | catalogued as COSV100382459; called by muse, mutect2, varscan2
- SLC8B1 | c.775C>T p.L259= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV99176766; called by muse, mutect2
- SLC9A4 | c.2160G>A p.R720= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV54829910; called by mutect2, varscan2
- SLCO1C1 | c.1662C>T p.F554= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as COSV56868784, COSV56871963; called by muse, mutect2, varscan2
- SLIT3 | c.1443G>A p.K481= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV60609274; called by muse, mutect2, varscan2
- SNTB1 | c.957G>A p.G319= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV101180038; called by muse, mutect2, varscan2
- SOX9 | c.1254C>T p.I418= | Silent (SNP) | VAF 14/143 reads (10%) | catalogued as COSV55428111, COSV99818339; called by muse, mutect2
- SPEF2 | c.2298G>A p.A766= | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as rs757644479, COSV61544601, COSV61551962; called by muse, mutect2
- SYNE1 | c.11097C>T p.F3699= (on ENST00000367255 / NM_182961.4; = p.F3684= on NM_033071.3) | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as rs1554520414, COSV99570609; ClinVar: uncertain significance; called by muse, mutect2
- TAF6L | c.297C>T p.L99= | Silent (SNP) | VAF 4/61 reads (7%) | catalogued as COSV99585295; called by muse, mutect2
- TAS2R9 | c.909C>T p.F303= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV53689393, COSV99553869; called by muse, mutect2
- TEX14 | c.1989G>A p.L663= (on ENST00000240361 / NM_001201457.2; = p.L657= on NM_031272.5) | Silent (SNP) | VAF 14/131 reads (11%) | catalogued as COSV99542716; called by muse, mutect2, varscan2
- TRAV21 | c.132C>T p.F44= | Silent (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2, varscan2
- TRPC4AP | c.954C>T p.F318= | Silent (SNP) | VAF 7/88 reads (8%) | catalogued as COSV52679797; called by muse, mutect2
- TSSK1B | c.312C>T p.T104= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV101181127; called by muse, mutect2, varscan2
- TTLL2 | c.1473G>A p.E491= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as rs1208372017, COSV53444936; called by muse, mutect2, varscan2
- UBASH3B | c.1713C>T p.I571= | Silent (SNP) | VAF 49/483 reads (10%) | catalogued as COSV99418226; called by muse, mutect2
- UGT2B4 | c.162T>G p.T54= | Silent (SNP) | VAF 19/171 reads (11%) | catalogued as COSV100522514; called by muse, mutect2, varscan2
- USP9X | c.4422C>T p.Y1474= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100199655; called by muse, mutect2, varscan2
- WDFY3 | c.5955A>G p.L1985= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as COSV99884318; called by muse, mutect2, varscan2
- WDFY3 | c.1827C>T p.L609= | Silent (SNP) | VAF 26/220 reads (12%) | catalogued as rs774439009, COSV99884324; called by muse, mutect2, varscan2
- WNT3A | c.285G>A p.L95= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV99469754; called by muse, mutect2, varscan2
- WNT9B | c.879C>T p.P293= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as rs746394872, COSV99255261; called by muse, mutect2, varscan2
- ZBTB21 | c.1686C>T p.H562= | Silent (SNP) | VAF 14/168 reads (8%) | catalogued as COSV100177219; called by muse, mutect2
- ZNF594 | c.1983C>T p.F661= | Silent (SNP) | VAF 9/129 reads (7%) | catalogued as rs1248208111, COSV101280520; called by muse, mutect2
- ZNF718 | c.1080C>T p.I360= | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as rs781907136, COSV68140609; called by muse, mutect2
- AL353804.4 | chrX:73823852 C>T | 5'Flank (SNP) | VAF 10/42 reads (24%) | catalogued as rs772294852; called by muse, mutect2, varscan2
- POMGNT1 | c.*360C>T | 3'UTR (SNP) | VAF 5/46 reads (11%) | catalogued as COSV100915685; called by muse, mutect2, varscan2
- POMGNT1 | c.*359C>T | 3'UTR (SNP) | VAF 5/47 reads (11%) | catalogued as rs1308180916, COSV100915686; called by mutect2, varscan2
- REG4 | c.*445C>T | 3'UTR (SNP) | VAF 11/145 reads (8%) | catalogued as COSV99858490; called by muse, mutect2
- USH1C | c.1285-7439G>A | Intron (SNP) | VAF 5/63 reads (8%) | catalogued as rs1354933414, COSV50015273, COSV99140551; called by muse, mutect2
- WNT16 | chr7:121325439 G>A | 5'Flank (SNP) | VAF 11/113 reads (10%) | catalogued as COSV55974912; called by muse, mutect2
- ZNF99 | c.*95G>A | 3'UTR (SNP) | VAF 9/100 reads (9%) | catalogued as rs878998317, COSV101233876; called by muse, mutect2
